Somatic mutation profile of tumor specimen TCGA-B5-A1MZ-01A (aliquot TCGA-B5-A1MZ-01A-11D-A142-09) from TCGA case TCGA-B5-A1MZ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G1; Age at diagnosis: 54.6 years (19,955 days).
Specimen TCGA-B5-A1MZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f86a2775-6af5-4d62-a791-998fdbb242d5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B5-A1MZ-10A (Blood Derived Normal), aliquot TCGA-B5-A1MZ-10A-01D-A142-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca08a1fa-4238-471a-843e-908596405026

The open-access MAF lists 58 somatic variants for this specimen: 47 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 10, Frame Shift Del 3, Splice Region 2, Splice Site 2, In Frame Del 1, Nonsense Mutation 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.95A>C p.D32A | Missense Mutation (SNP) | VAF 19/47 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs121913396, COSV62688001, COSV62688037, COSV62688249; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBXW7 | c.1435C>G p.R479G (on ENST00000281708 / NM_001349798.2; = p.R399G on NM_018315.5) | Missense Mutation (SNP) | VAF 7/11 reads (64%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747241612, COSV55894141, COSV55894999, COSV55908957; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR2 | c.755C>G p.S252W | Missense Mutation (SNP) | VAF 37/75 reads (49%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs79184941, CM950458, CM970526, COSV60638319; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- KAT6A | c.4645G>A p.G1549S | Missense Mutation (SNP) | VAF 60/140 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1064794000, COSV55907802; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- PTEN | c.80-1_80del p.X27_splice | Splice Site (DEL) | VAF 9/38 reads (24%) | catalogued as rs1554893747; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PTEN | c.625G>T p.G209* | Nonsense Mutation (SNP) | VAF 5/9 reads (56%) | catalogued as rs765433422, COSV64294737, COSV99057830; ClinVar: pathogenic; called by muse, mutect2, varscan2
- C5AR1 | c.604G>A p.V202M | Missense Mutation (SNP) | VAF 52/132 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1391265684, COSV61892510, COSV61893553; called by muse, mutect2, varscan2
- CCN4 | c.709C>T p.R237W | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781544299, COSV51529294, COSV51530489; called by muse, mutect2, varscan2
- CHD4 | c.3274C>T p.R1092W (on ENST00000357008 / NM_001363606.2; = p.R1105W on NM_001273.5) | Missense Mutation (SNP) | VAF 27/76 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58898720; called by muse, mutect2, varscan2
- CHD4 | c.2936G>A p.R979Q (on ENST00000357008 / NM_001363606.2; = p.R992Q on NM_001273.5) | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV58900604; called by muse, mutect2, varscan2
- CYFIP1 | c.3268C>G p.L1090V | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as COSV100488293; called by muse, mutect2, varscan2
- DEPDC1 | c.1531C>G p.Q511E | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.68); PolyPhen benign (0.169); catalogued as COSV100920338; called by muse, mutect2, varscan2
- FAM186B | c.2327G>A p.R776Q | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.006); catalogued as rs759878663, COSV57722026; called by muse, mutect2, varscan2
- GPR119 | c.328C>G p.P110A | Missense Mutation (SNP) | VAF 12/28 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99358637; called by muse, mutect2, varscan2
- HNRNPDL | c.995G>C p.R332P | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.689); catalogued as COSV55022200, COSV99787105; called by muse, mutect2, varscan2
- KCNE4 | c.182C>T p.T61M | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs1484402588, COSV99918981; called by muse, varscan2
- KCNG1 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100857093; called by muse, varscan2
- KNL1 | c.740G>T p.R247I (on ENST00000346991 / NM_170589.5; = p.R221I on NM_144508.5) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV61153331; called by muse, mutect2, varscan2
- LIG1 | c.2557C>T p.P853S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV99618963; called by muse, mutect2, varscan2
- LRRFIP1 | c.471G>C p.L157F (on ENST00000392000 / NM_001137552.2; = p.L285F on NM_001137550.2) | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99790824; called by muse, mutect2, varscan2
- MAP3K15 | c.2387C>T p.S796L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1196541709, COSV100134838; called by muse, mutect2, varscan2
- MBD3 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.815); catalogued as COSV99336982; called by muse, mutect2, varscan2
- MOB3B | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT tolerated (0.64); PolyPhen benign (0.005); catalogued as COSV99218582; called by muse, mutect2
- MYCBP | c.295_297del p.E99del | In Frame Del (DEL) | VAF 12/38 reads (32%) | catalogued as rs767731915; called by pindel, varscan2
- N6AMT1 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.2); PolyPhen benign (0.074); catalogued as COSV100374995, COSV58135354; called by muse, mutect2, varscan2
- PRELID2 | c.115A>G p.I39V (on ENST00000334744 / NM_182960.4; = p.I10V on NM_138492.6) | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.47); PolyPhen benign (0.003); catalogued as rs761566160, COSV100597163; called by muse, mutect2, varscan2
- PSG2 | c.59T>A p.V20D | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as COSV101290484; called by muse, mutect2, varscan2
- PVR | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); catalogued as COSV99495817; called by muse, mutect2, varscan2
- RASIP1 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.21); PolyPhen benign (0.098); catalogued as COSV99710823; called by muse, mutect2, varscan2
- RUFY3 | c.614G>A p.G205E | Missense Mutation (SNP) | VAF 33/75 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99887442; called by muse, mutect2, varscan2
- RUVBL1 | c.967A>G p.I323V | Missense Mutation (SNP) | VAF 17/63 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.039); catalogued as rs774903268, COSV100494191; called by muse, mutect2, varscan2
- SCAF4 | c.1236+1G>A p.X412_splice | Splice Site (SNP) | VAF 8/23 reads (35%) | catalogued as COSV99741518; called by muse, mutect2, varscan2
- SEC16A | c.6447G>A p.E2149= | Splice Region (SNP) | VAF 29/86 reads (34%) | catalogued as COSV99258524; called by muse, mutect2, varscan2
- SLC16A11 | c.1255G>A p.G419S (on ENST00000308009; = p.G395S on NM_153357.3) | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs138521125, COSV100338653, COSV100338754; called by muse, varscan2
- SPECC1L | c.851A>G p.N284S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as rs200451144, COSV100062452; called by muse, varscan2
- TEX11 | c.1197T>A p.F399L (on ENST00000344304; = p.F384L on NM_031276.3) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV100721782; called by muse, mutect2, varscan2
- TRBJ2-1 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 21/61 reads (34%) | catalogued as rs1554511359; called by muse, mutect2, varscan2
- UPF3B | c.250dup p.S84Ffs*2 | Frame Shift Ins (INS) | VAF 8/33 reads (24%) | catalogued as rs1171504530; called by mutect2, varscan2
- USP11 | c.2803C>T p.R935C (on ENST00000218348; = p.R892C on NM_001371072.1) | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.899); catalogued as rs1163328387, COSV99510950; called by muse, mutect2, varscan2
- WASHC2C | c.3119C>T p.P1040L (on ENST00000336378; = p.P1019L on NM_015262.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 59/157 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs1358309249; called by muse, mutect2, varscan2
- YWHAE | c.717T>C p.G239= | Splice Region (SNP) | VAF 23/50 reads (46%) | catalogued as COSV99981236; called by muse, mutect2, varscan2
- ZNF236 | c.3428C>T p.A1143V | Missense Mutation (SNP) | VAF 13/23 reads (57%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as rs1451029127, COSV99470441; called by muse, mutect2, varscan2
- ARID1A | c.3092_3106delinsG p.T1031Sfs*11 | Frame Shift Del (DEL) | VAF 53/141 reads (38%) | called by pindel, varscan2*
- ARID1A | c.3338_3348del p.P1113Hfs*6 | Frame Shift Del (DEL) | VAF 14/40 reads (35%) | called by mutect2, pindel, varscan2
- C12orf50 | c.45_46del p.Q16Afs*28 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- KIR2DL3 | c.367A>C p.T123P | Missense Mutation (SNP) | VAF 72/276 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- CDK17 | c.693A>C p.A231= | Silent (SNP) | VAF 36/100 reads (36%) | catalogued as COSV99702784; called by muse, mutect2, varscan2
- CLDN15 | c.162C>T p.T54= | Silent (SNP) | VAF 48/114 reads (42%) | catalogued as rs1267714270, COSV99778951; called by muse, mutect2, varscan2
- COL6A3 | c.5148C>T p.H1716= | Silent (SNP) | VAF 48/135 reads (36%) | catalogued as rs114845780, COSV55098400; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUOX2 | c.1419C>T p.A473= | Silent (SNP) | VAF 22/42 reads (52%) | catalogued as COSV101199783; called by muse, mutect2, varscan2
- ELOA2 | c.27C>T p.H9= | Silent (SNP) | VAF 18/53 reads (34%) | catalogued as COSV99796781; called by muse, mutect2, varscan2
- HHIPL1 | c.549G>A p.Q183= | Silent (SNP) | VAF 28/69 reads (41%) | catalogued as COSV100415162; called by muse, mutect2, varscan2
- HJURP | c.1146G>A p.S382= | Silent (SNP) | VAF 21/46 reads (46%) | catalogued as rs201340488, COSV100982603; called by muse, mutect2, varscan2
- MIOS | c.1485G>A p.Q495= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as rs201044877, COSV100402801; called by muse, mutect2, varscan2
- MTMR8 | c.1962C>A p.I654= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV100878448; called by muse, mutect2, varscan2
- THBS2 | c.3009C>T p.D1003= | Silent (SNP) | VAF 12/46 reads (26%) | catalogued as rs752811163, COSV100827916, COSV100827927; called by muse, mutect2, varscan2
- AC024940.1 | n.2276C>T | RNA (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
